TCGA case TCGA-PR-A5PG — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4ee51f8b-ca57-404d-80b3-ccd66735260b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (4)
1. Pheochromocytoma, malignant (the primary disease): ICD-O-3 morphology code: 8700/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.6 years (15,577 days); Year of diagnosis: 2007; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,485 days (6.8 years); Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 12.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Pheochromocytoma, malignant), site: Lung, NOS. Age at diagnosis: 48.9 years (17,855 days); Days to diagnosis: 2,278 days (6.2 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Pheochromocytoma, malignant), site: Liver. Age at diagnosis: 48.9 years (17,855 days); Days to diagnosis: 2,278 days (6.2 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Pheochromocytoma, malignant), site: Bone, NOS. Age at diagnosis: 48.9 years (17,855 days); Days to diagnosis: 2,278 days (6.2 years); Prior treatment: Yes.

Follow-up (7 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 1,094 days (3.0 years); Disease response: Tumor Free.
- Day 2,278 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 2,278 days (6.2 years); Evidence of progression type: Convincing Image Source.
- Day 2,278 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 2,278 days (6.2 years); Evidence of progression type: Convincing Image Source.
- Day 2,278 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 2,278 days (6.2 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 2,485 days (6.8 years); Disease response: With Tumor.
- Karnofsky performance status: 100; Timepoint: Preoperative.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-PR-A5PG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 240 mg.
  Slide TCGA-PR-A5PG-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-PR-A5PG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-PR-A5PG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Histologic diagnosis: Pheochromocytoma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,485 days; disease-specific survival: no event (censored), 2,485 days; disease-free interval: event (new tumor event after initially disease-free), 2,278 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,278 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-PR-A5PG-01A-11D-A35C-01): tumor purity 0.84, ploidy 1.96, whole-genome doublings 0.
